Somatic mutation profile of tumor specimen HCM-BROD-0449-C34-86M (aliquot HCM-BROD-0449-C34-86M-01D-A937-36) from HCMI case HCM-BROD-0449-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.3 years (26,423 days).
Specimen HCM-BROD-0449-C34-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaad1443-59dc-4804-9a96-048ac59a846b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0449-C34-10B (Blood Derived Normal), aliquot HCM-BROD-0449-C34-10B-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2e1a05a-a662-4213-9eb2-2e2165f17759

The open-access MAF lists 221 somatic variants for this specimen: 165 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 49, Nonsense Mutation 14, Intron 4, In Frame Del 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 554/555 reads (100%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 161/162 reads (99%) | hotspot (GDC flag); catalogued as rs786204864, CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs531506351; called by muse, mutect2, varscan2
- ACSL1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55666071; called by muse, mutect2, varscan2
- ADGRB3 | c.1322G>T p.W441L | Missense Mutation (SNP) | VAF 228/450 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV65393597; called by muse, mutect2, varscan2
- ANKRD17 | c.6960A>G p.S2320= | Splice Region (SNP) | VAF 113/232 reads (49%) | catalogued as rs766144116; called by muse, mutect2, varscan2
- APCS | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 265/470 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54819307; called by muse, mutect2, varscan2
- ARPP21 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 380/381 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs376713321, COSV51793709; called by muse, mutect2, varscan2
- ATG9A | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 302/465 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769517669; called by muse, mutect2, varscan2
- ATR | c.7631G>A p.R2544H | Missense Mutation (SNP) | VAF 67/582 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769121210, COSV63387461; called by muse, mutect2, varscan2
- BIRC6 | c.11696A>T p.K3899I | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV70195699; called by muse, mutect2, varscan2
- C1orf115 | c.404C>G p.T135S | Missense Mutation (SNP) | VAF 255/467 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs754626511; called by muse, varscan2
- CCDC39 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 106/500 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV99866648; called by muse, mutect2, varscan2
- CLCA4 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 334/335 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV55367081; called by muse, mutect2, varscan2
- CPEB4 | c.1883C>A p.A628E | Missense Mutation (SNP) | VAF 199/400 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99437595; called by muse, mutect2, varscan2
- CTCFL | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 147/352 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54770144; called by muse, mutect2, varscan2
- CUTA | c.170C>G p.S57W (on ENST00000488034 / NM_001014840.2; = p.S34W on NM_015921.3) | Missense Mutation (SNP) | VAF 532/1038 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV53378281; called by muse, mutect2, varscan2
- DGKB | c.1991T>A p.I664K | Missense Mutation (SNP) | VAF 473/474 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99337055; called by muse, mutect2, varscan2
- DNAH11 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 498/499 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs760400011, COSV100180719; called by muse, mutect2, varscan2
- EBF2 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 233/234 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV68776356; called by muse, mutect2, varscan2
- EML1 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772174519, COSV51746088; called by muse, mutect2, varscan2
- EVX2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 190/514 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57962699; called by muse, mutect2, varscan2
- FRG2B | c.773C>A p.A258D | Missense Mutation (SNP) | VAF 96/742 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1025315873; called by muse, mutect2
- FYN | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 384/764 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV57615055; called by muse, mutect2, varscan2
- GALNT13 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 208/351 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101222537, COSV67215488; called by muse, mutect2, varscan2
- GFM1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 97/450 reads (22%) | catalogued as rs771890880, COSV99963100; called by muse, mutect2, varscan2
- GLYATL2 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 248/251 reads (99%) | catalogued as COSV54849551; called by muse, mutect2, varscan2
- GRB14 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 183/302 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1240225857; called by muse, mutect2
- HOXD9 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 225/616 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs1185539872; called by muse, mutect2, varscan2
- HRAS | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 63/880 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54245262; called by muse, mutect2
- HUWE1 | c.10447A>C p.T3483P | Missense Mutation (SNP) | VAF 268/271 reads (99%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53338931; called by muse, varscan2
- IGKV3-15 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs745796620; called by mutect2, varscan2
- KCNA1 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 187/763 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230111; called by muse, mutect2, varscan2
- KCNC4 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 406/821 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as rs369670720; called by muse, mutect2, varscan2
- KLHL1 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 214/214 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100918162, COSV64777211; called by muse, mutect2, varscan2
- KLHL1 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as rs144761752; called by muse, mutect2, varscan2
- LAMB3 | c.1699T>C p.C567R | Missense Mutation (SNP) | VAF 301/1158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61917442; called by muse, mutect2
- LIPC | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 275/276 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs540524619; called by muse, mutect2, varscan2
- LPO | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 24/844 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV99228785; called by muse, mutect2
- MACF1 | c.4261G>C p.E1421Q | Missense Mutation (SNP) | VAF 180/180 reads (100%) | catalogued as COSV58359132; called by muse, mutect2, varscan2
- MAML3 | c.2474C>A p.T825K | Missense Mutation (SNP) | VAF 314/315 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV101558283; called by muse, mutect2, varscan2
- MELTF | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 297/598 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs762942426, COSV56382344, COSV99586326; called by muse, mutect2, varscan2
- METTL6 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 468/468 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs540802719; called by muse, mutect2, varscan2
- MMP16 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 167/353 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54170667; called by muse, mutect2, varscan2
- NCAM2 | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 291/463 reads (63%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.5); catalogued as rs1396341533; called by muse, mutect2, varscan2
- NIM1K | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 168/403 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771487658; called by muse, mutect2, varscan2
- NLRP8 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 192/356 reads (54%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs201546502, COSV52586071; called by muse, mutect2, varscan2
- OPCML | c.805G>C p.G269R | Missense Mutation (SNP) | VAF 427/428 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1442244590, COSV100099132, COSV59412062; called by muse, mutect2, varscan2
- OR52B6 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 113/578 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs1168098948, COSV61448074; called by muse, mutect2, varscan2
- PAQR4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 566/568 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.678); catalogued as rs748157967; called by muse, mutect2, varscan2
- PCDH12 | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 336/339 reads (99%) | catalogued as COSV99190108; called by muse, mutect2, varscan2
- PCDHGB7 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 387/388 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.378); catalogued as rs755798236, COSV99548670; called by muse, mutect2, varscan2
- PPHLN1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as rs781307689; called by muse, mutect2, varscan2
- PPM1D | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 323/587 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV100011095; called by muse, mutect2, varscan2
- PYGO2 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 450/812 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.133); catalogued as rs866373283, COSV63757621; called by muse, mutect2, varscan2
- RGS5 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 186/447 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV58352000; called by muse, mutect2, varscan2
- RPN1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 351/660 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56190268; called by muse, mutect2, varscan2
- SCN2A | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1228890159, COSV51849978; called by muse, mutect2, varscan2
- SLC25A42 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 239/579 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs202000540; called by muse, mutect2, varscan2
- SP140 | c.2149C>A p.H717N | Missense Mutation (SNP) | VAF 160/265 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59453840; called by muse, varscan2
- SPAG5 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 102/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199294215; called by muse, mutect2, varscan2
- TBXT | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 535/536 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs775012230, COSV51616284; called by muse, mutect2, varscan2
- TEAD4 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 663/664 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs371373848; called by muse, mutect2, varscan2
- TM9SF2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 234/451 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV64507136; called by muse, mutect2, varscan2
- TRIM69 | c.1075G>C p.E359Q (on ENST00000329464 / NM_182985.5; = p.E200Q on NM_080745.5) | Missense Mutation (SNP) | VAF 446/447 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs776968166; called by muse, mutect2, varscan2
- TTN | c.69490G>A p.V23164I (on ENST00000591111; = p.V15740I on NM_003319.4) | Missense Mutation (SNP) | VAF 319/516 reads (62%) | PolyPhen probably damaging (0.991); catalogued as rs371306826; called by muse, mutect2, varscan2
- TTN | c.58141C>G p.R19381G (on ENST00000591111; = p.R11957G on NM_003319.4) | Missense Mutation (SNP) | VAF 257/415 reads (62%) | PolyPhen probably damaging (0.998); catalogued as COSV59879754; called by muse, mutect2, varscan2
- XDH | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 170/515 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101052175; called by muse, mutect2, varscan2
- ZDBF2 | c.616A>G p.S206G | Missense Mutation (SNP) | VAF 270/452 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1475184233; called by muse, mutect2, varscan2
- ZFHX4 | c.7915G>A p.A2639T | Missense Mutation (SNP) | VAF 145/286 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99266465; called by muse, mutect2, varscan2
- ZFHX4 | c.8807T>C p.M2936T | Missense Mutation (SNP) | VAF 145/303 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51445952; called by muse, mutect2, varscan2
- ZNF423 | c.1230G>T p.Q410H (on ENST00000563137 / NM_001379286.1; = p.Q402H on NM_015069.4) | Missense Mutation (SNP) | VAF 382/383 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV52178927; called by muse, mutect2, varscan2
- ZNF471 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 152/288 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57290083; called by muse, mutect2, varscan2
- ZNF705A | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 158/619 reads (26%) | catalogued as COSV63733572; called by muse, mutect2, varscan2
- AC131160.1 | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 36/1008 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- ADCY8 | c.2039G>C p.G680A | Missense Mutation (SNP) | VAF 390/1027 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ADRA2A | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 225/228 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AL645922.1 | c.3322G>T p.A1108S | Missense Mutation (SNP) | VAF 329/726 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- B4GALT6 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- BPNT2 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 463/738 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- BRWD3 | c.3045G>T p.M1015I | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C17orf99 | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 34/818 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.775); called by muse, mutect2
- C4orf50 | c.3G>A p.M1? (on ENST00000324058; = p.M1233I on NM_001364689.1 and 1 other RefSeq transcript) | Translation Start Site (SNP) | VAF 144/144 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP8 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CATSPERG | c.2888A>G p.Y963C | Missense Mutation (SNP) | VAF 333/583 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELSR1 | c.1896C>G p.I632M | Missense Mutation (SNP) | VAF 222/441 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DLEC1 | c.3213G>T p.Q1071H | Missense Mutation (SNP) | VAF 365/365 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- DOCK8 | c.1205_1208del p.A402Gfs*4 | Frame Shift Del (DEL) | VAF 152/387 reads (39%) | called by mutect2, pindel, varscan2
- DOP1B | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNB3 | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 65/603 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- EGLN2 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 257/624 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FANCD2 | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 483/484 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- FBN2 | c.741G>C p.W247C | Missense Mutation (SNP) | VAF 345/345 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL6 | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 247/673 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- FOLH1 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 310/320 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRG2 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 303/353 reads (86%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FRG2C | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 189/1463 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- GALC | c.1628C>G p.A543G | Missense Mutation (SNP) | VAF 34/349 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- GJA10 | c.785A>T p.K262M | Missense Mutation (SNP) | VAF 377/722 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GLYATL2 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 250/251 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPC5 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 414/415 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GTPBP3 | c.1253T>A p.V418E | Missense Mutation (SNP) | VAF 290/292 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, varscan2
- GUCY2D | c.2035G>C p.V679L | Missense Mutation (SNP) | VAF 372/372 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HOXC5 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 529/531 reads (100%) | SIFT tolerated (0.62); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IDO2 | c.252C>A p.H84Q (on ENST00000389060; = p.H97Q on NM_194294.2) | Missense Mutation (SNP) | VAF 191/481 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IGFN1 | c.2383G>T p.D795Y (on ENST00000295591 / NM_001367841.1; = p.D3252Y on NM_001164586.2) | Missense Mutation (SNP) | VAF 177/460 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- IGKV1D-16 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 307/525 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IRF8 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 276/279 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ITGA11 | c.370del p.L124Sfs*66 | Frame Shift Del (DEL) | VAF 318/458 reads (69%) | called by mutect2, pindel, varscan2
- LDLR | c.2018G>C p.S673T | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- LRP2 | c.9861G>T p.L3287F | Missense Mutation (SNP) | VAF 241/381 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- LRP2 | c.7965T>A p.C2655* | Nonsense Mutation (SNP) | VAF 97/278 reads (35%) | called by muse, mutect2, varscan2
- MAGEB1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 102/411 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MGA | c.4490C>G p.S1497* | Nonsense Mutation (SNP) | VAF 276/278 reads (99%) | called by muse, mutect2, varscan2
- MPO | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 325/607 reads (54%) | called by muse, mutect2, varscan2
- MRPL40 | c.501C>G p.N167K | Missense Mutation (SNP) | VAF 184/398 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MSC | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 200/584 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- MTBP | c.2222T>C p.L741P | Missense Mutation (SNP) | VAF 165/461 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH7 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO15A | c.1301A>T p.E434V | Missense Mutation (SNP) | VAF 480/1384 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1F | c.2640G>C p.K880N | Missense Mutation (SNP) | VAF 380/381 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCOA2 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 326/539 reads (60%) | called by muse, mutect2, varscan2
- NCOR1 | c.1546_1548del p.E516del | In Frame Del (DEL) | VAF 80/84 reads (95%) | called by pindel, varscan2
- NEB | c.4996G>T p.E1666* | Nonsense Mutation (SNP) | VAF 192/313 reads (61%) | called by muse, mutect2, varscan2
- NIN | c.5696A>G p.N1899S (on ENST00000382041 / NM_182946.1; = p.N1186S on NM_016350.4) | Missense Mutation (SNP) | VAF 465/466 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLE1 | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 280/653 reads (43%) | called by muse, mutect2, varscan2
- NPHP3 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 83/465 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NSD3 | c.3450C>G p.I1150M | Missense Mutation (SNP) | VAF 61/473 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, varscan2
- OR2AK2 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 222/414 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- PHF20L1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 292/768 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIK3CA | c.2011T>G p.L671V | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB1 | c.991C>G p.H331D | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POGZ | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 80/843 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2
- PPP1R14D | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 291/292 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PRDM13 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 262/596 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRKD1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 330/331 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAD54L2 | c.1043A>G p.N348S | Missense Mutation (SNP) | VAF 303/304 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- RANBP17 | c.2210A>G p.Y737C | Missense Mutation (SNP) | VAF 259/259 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RGS22 | c.935_952del p.C312_S317del | In Frame Del (DEL) | VAF 101/541 reads (19%) | called by mutect2, pindel, varscan2
- RPEL1 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 550/555 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCML2 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 328/329 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SEC63 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 253/521 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SERPINB3 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 299/300 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3B4 | c.356C>G p.T119S | Missense Mutation (SNP) | VAF 333/624 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC12A2 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMCR8 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 346/1089 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM267 | c.428T>A p.F143Y | Missense Mutation (SNP) | VAF 327/714 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- TMEM72 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 48/318 reads (15%) | called by muse, mutect2, varscan2
- TNKS | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 523/524 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNN | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 472/838 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- TNR | c.3193dup p.R1065Kfs*5 | Frame Shift Ins (INS) | VAF 238/531 reads (45%) | called by mutect2, pindel, varscan2
- TOP3A | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 236/728 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRAJ41 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 230/230 reads (100%) | called by muse, mutect2, varscan2
- TRHR | c.1183T>A p.F395I | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC4 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 116/117 reads (99%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- TSPOAP1 | c.5414A>G p.D1805G | Missense Mutation (SNP) | VAF 254/538 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.32456C>A p.P10819Q (on ENST00000591111; = p.P9892Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/334 reads (60%) | PolyPhen benign (0.134); called by muse, mutect2, varscan2
- UBR5 | c.4787C>G p.A1596G | Missense Mutation (SNP) | VAF 54/475 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VIRMA | c.5294C>T p.P1765L | Missense Mutation (SNP) | VAF 143/363 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- WDR26 | c.1723T>G p.L575V (on ENST00000414423 / NM_001379403.1; = p.L475V on NM_025160.7) | Missense Mutation (SNP) | VAF 193/327 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ZFHX4 | c.7083C>A p.Y2361* | Nonsense Mutation (SNP) | VAF 147/300 reads (49%) | called by muse, mutect2, varscan2
- ZNF429 | c.1861T>C p.Y621H | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZNF441 | c.60G>T p.L20F | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ZNF571 | c.571G>C p.G191R | Missense Mutation (SNP) | VAF 76/482 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF707 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 888/1407 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- ACSM4 | c.429G>T p.P143= | Silent (SNP) | VAF 432/432 reads (100%) | catalogued as COSV101257044; called by muse, mutect2, varscan2
- ADRM1 | c.382C>T p.L128= | Silent (SNP) | VAF 296/296 reads (100%) | catalogued as COSV53351989, COSV53366612; called by muse, varscan2
- ATP13A1 | c.1227G>T p.G409= | Silent (SNP) | VAF 454/458 reads (99%) | called by muse, mutect2, varscan2
- BMP6 | c.1428G>T p.P476= | Silent (SNP) | VAF 291/622 reads (47%) | catalogued as COSV99307230; called by muse, varscan2
- CABS1 | c.822T>A p.A274= | Silent (SNP) | VAF 277/277 reads (100%) | called by muse, mutect2, varscan2
- CDH20 | c.2355G>A p.R785= | Silent (SNP) | VAF 470/470 reads (100%) | called by muse, mutect2, varscan2
- CYFIP2 | c.2874A>G p.L958= (on ENST00000616178 / NM_001291722.2; = p.L933= on NM_014376.4) | Silent (SNP) | VAF 237/237 reads (100%) | called by muse, mutect2, varscan2
- DAO | c.868C>A p.R290= | Silent (SNP) | VAF 152/313 reads (49%) | catalogued as COSV57321304; called by muse, mutect2, varscan2
- DDI2 | c.339A>G p.P113= | Silent (SNP) | VAF 258/258 reads (100%) | called by muse, mutect2, varscan2
- FLG | c.10524A>G p.E3508= | Silent (SNP) | VAF 252/660 reads (38%) | catalogued as rs567642253; called by muse, mutect2, varscan2
- FRG2 | c.594C>A p.I198= | Silent (SNP) | VAF 302/353 reads (86%) | called by muse, mutect2, varscan2
- GABRA6 | c.453C>A p.T151= | Silent (SNP) | VAF 213/214 reads (100%) | called by muse, mutect2, varscan2
- GJC3 | c.36G>A p.E12= | Silent (SNP) | VAF 283/283 reads (100%) | catalogued as rs569274106; called by muse, mutect2, varscan2
- IGKV3-15 | c.60A>T p.G20= | Silent (SNP) | VAF 50/271 reads (18%) | catalogued as rs561717275; called by muse, mutect2, varscan2
- INTS8 | c.2577A>T p.A859= | Silent (SNP) | VAF 302/479 reads (63%) | catalogued as rs942716871; called by muse, mutect2, varscan2
- ITGB6 | c.1962G>T p.A654= | Silent (SNP) | VAF 238/392 reads (61%) | catalogued as rs201818641, COSV51796580; called by muse, mutect2, varscan2
- KPRP | c.126G>A p.E42= | Silent (SNP) | VAF 60/755 reads (8%) | called by muse, mutect2
- LRRC4B | c.1125C>T p.V375= | Silent (SNP) | VAF 360/640 reads (56%) | catalogued as COSV65349527; called by muse, mutect2, varscan2
- MDH1 | c.627T>G p.V209= | Silent (SNP) | VAF 117/435 reads (27%) | called by muse, mutect2, varscan2
- OBSCN | c.9099C>T p.Y3033= | Silent (SNP) | VAF 233/916 reads (25%) | catalogued as rs371187428; called by muse, mutect2, varscan2
- OR10G4 | c.864C>G p.T288= | Silent (SNP) | VAF 411/412 reads (100%) | called by muse, mutect2, varscan2
- OR4D9 | c.714C>T p.S238= | Silent (SNP) | VAF 449/451 reads (100%) | catalogued as rs1213957182; called by muse, mutect2, varscan2
- PCDHGB7 | c.108G>T p.S36= | Silent (SNP) | VAF 38/494 reads (8%) | catalogued as COSV99549407; called by muse, mutect2
- PLEC | c.12162C>T p.S4054= (on ENST00000322810 / NM_201380.4; = p.S3944= on NM_000445.5) | Silent (SNP) | VAF 306/757 reads (40%) | catalogued as rs782402718; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEG | c.573C>A p.L191= | Silent (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- PPP1R37 | c.1419C>T p.S473= | Silent (SNP) | VAF 277/613 reads (45%) | called by muse, mutect2, varscan2
- PRKCB | c.1683C>T p.P561= | Silent (SNP) | VAF 227/228 reads (100%) | called by muse, mutect2, varscan2
- RASGEF1B | c.846A>T p.R282= | Silent (SNP) | VAF 245/245 reads (100%) | called by muse, mutect2, varscan2
- ROS1 | c.1575T>C p.F525= | Silent (SNP) | VAF 268/556 reads (48%) | called by muse, mutect2, varscan2
- RPA1 | c.1702C>A p.R568= | Silent (SNP) | VAF 247/247 reads (100%) | called by muse, mutect2, varscan2
- RRP36 | c.633C>T p.F211= | Silent (SNP) | VAF 205/437 reads (47%) | called by muse, mutect2, varscan2
- SGO2 | c.2055C>G p.T685= | Silent (SNP) | VAF 152/476 reads (32%) | called by muse, mutect2, varscan2
- SLC6A17 | c.1017C>A p.I339= | Silent (SNP) | VAF 363/719 reads (50%) | catalogued as COSV58996635; called by muse, mutect2, varscan2
- SNRNP200 | c.5346G>A p.S1782= | Silent (SNP) | VAF 263/426 reads (62%) | catalogued as rs756239767, COSV60493952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX27 | c.1542C>T p.F514= | Silent (SNP) | VAF 306/543 reads (56%) | catalogued as rs761223156, COSV64325782; called by muse, mutect2, varscan2
- SUZ12 | c.684G>T p.P228= | Silent (SNP) | VAF 300/602 reads (50%) | called by muse, mutect2, varscan2
- TFEB | c.1332G>C p.P444= | Silent (SNP) | VAF 348/706 reads (49%) | called by muse, mutect2, varscan2
- TMC8 | c.285C>A p.L95= | Silent (SNP) | VAF 149/648 reads (23%) | called by muse, mutect2, varscan2
- TMCC1 | c.300A>G p.T100= | Silent (SNP) | VAF 169/807 reads (21%) | called by muse, mutect2, varscan2
- TRIO | c.6384A>G p.L2128= | Silent (SNP) | VAF 47/577 reads (8%) | called by muse, mutect2
- TUBA3E | c.1224C>T p.Y408= | Silent (SNP) | VAF 124/613 reads (20%) | catalogued as rs574854736; called by muse, mutect2
- UNC79 | c.6288G>T p.P2096= (on ENST00000393151 / NM_001346218.2; = p.P1919= on NM_020818.5) | Silent (SNP) | VAF 427/427 reads (100%) | catalogued as rs753101383, COSV56380645; called by muse, mutect2, varscan2
- USP19 | c.1338A>T p.T446= | Silent (SNP) | VAF 87/342 reads (25%) | called by muse, mutect2, varscan2
- VEGFC | c.399A>G p.P133= | Silent (SNP) | VAF 257/258 reads (100%) | called by muse, mutect2, varscan2
- YARS2 | c.192C>T p.L64= | Silent (SNP) | VAF 679/682 reads (100%) | called by muse, mutect2, varscan2
- ZNF425 | c.240G>A p.R80= | Silent (SNP) | VAF 165/166 reads (99%) | called by muse, mutect2, varscan2
- ZNF571 | c.570T>A p.T190= | Silent (SNP) | VAF 74/480 reads (15%) | called by muse, mutect2, varscan2
- ZNF727 | c.1149G>T p.L383= | Silent (SNP) | VAF 286/287 reads (100%) | called by muse, mutect2, varscan2
- ZNF814 | c.1683C>A p.G561= | Silent (SNP) | VAF 277/530 reads (52%) | called by muse, mutect2, varscan2
- FRRS1L | c.-58C>T | 5'UTR (SNP) | VAF 199/377 reads (53%) | catalogued as rs1280023187; called by muse, mutect2, varscan2
- HBS1L | c.430+2480C>T | Intron (SNP) | VAF 122/550 reads (22%) | catalogued as rs1442253987; called by muse, mutect2, varscan2
- MACF1 | c.15832-11630C>T | Intron (SNP) | VAF 353/354 reads (100%) | called by muse, mutect2, varscan2
- NSUN4 | c.94-1290C>G | Intron (SNP) | VAF 195/195 reads (100%) | called by muse, mutect2, varscan2
- SCAI | c.99-9999C>T | Intron (SNP) | VAF 134/134 reads (100%) | called by muse, mutect2, varscan2
- SLC25A1P5 | n.199C>T | RNA (SNP) | VAF 140/254 reads (55%) | called by muse, mutect2, varscan2
- TMEM99 | n.823C>T | RNA (SNP) | VAF 345/668 reads (52%) | catalogued as rs191706937; called by muse, mutect2, varscan2
